Somatic mutation profile of tumor specimen ER-ABF0-TTP1-A (aliquot ER-ABF0-TTP1-A-1-0-D-A46L-34) from EXCEPTIONAL_RESPONDERS case ER-ABF0, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.1 years (19,042 days).
Specimen ER-ABF0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcae7676-3081-42ca-a4a4-57e068c1f0ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ABF0-NB1-A (Blood Derived Normal), aliquot ER-ABF0-NB1-A-1-0-D-A76D-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6637e2e8-fefc-4899-94d2-aec304fbd0c7

The open-access MAF lists 179 somatic variants for this specimen: 131 protein-altering or splice-affecting, 29 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 29, Frame Shift Del 11, 3'UTR 10, Nonsense Mutation 6, In Frame Del 4, Intron 4, Splice Site 3, RNA 2, 5'UTR 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 25/83 reads (30%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- AFP | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs780261526, COSV99890221; called by mutect2, varscan2
- ATP2C2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1304628817, COSV99298663; called by mutect2, varscan2
- CADM3 | c.268C>A p.P90T (on ENST00000368125 / NM_001127173.3; = p.P124T on NM_021189.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as COSV63686465; called by muse, mutect2, varscan2
- CCDC178 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs765016210; called by muse, mutect2, varscan2
- CCDC22 | c.1773C>T p.I591= | Splice Region (SNP) | VAF 61/194 reads (31%) | catalogued as rs1557115183; called by muse, mutect2, varscan2
- CD40LG | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768138040, COSV65699185; called by muse, mutect2, varscan2
- CDC20 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs761176631; called by muse, mutect2, varscan2
- CEACAM4 | c.424+1G>A p.X142_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as rs1466280079, COSV55730659; called by muse, mutect2, varscan2
- CHRNB3 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs185338940; called by muse, mutect2, varscan2
- CLIC2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs781890715, COSV58936924; called by muse, mutect2, varscan2
- CLSPN | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs775380330; called by muse, mutect2, varscan2
- CNTNAP2 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs747922335, COSV62158230, COSV99080851; called by muse, mutect2, varscan2
- F5 | c.6299G>A p.R2100H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs772248818, COSV63128032; called by mutect2, varscan2
- F9 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as CM940494, COSV54382897; called by muse, mutect2, varscan2
- GCM2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV104432740, COSV104432741; called by muse, mutect2, varscan2
- HNRNPDL | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs988284711, COSV55023147; called by mutect2, varscan2
- HSPD1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs745574190; called by muse, mutect2
- KATNIP | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV55182062, COSV55188507; called by muse, mutect2, varscan2
- L3MBTL3 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62386117; called by muse, mutect2
- MYADML2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs566307177; called by mutect2, varscan2
- MYBPC2 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV63093142; called by muse, mutect2
- MYLK | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs202225055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBPF14 | c.2615A>G p.E872G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430421905; called by muse, varscan2
- OR2A4 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59575836; called by muse, mutect2, varscan2
- PARP12 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1335750191; called by muse, mutect2, varscan2
- PCDHGA2 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs1169653888, COSV53926179; called by muse, mutect2
- PEX1 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1307075489; called by muse, mutect2, varscan2
- PLEKHA5 | c.492G>T p.R164S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54706359; called by muse, mutect2
- PSG6 | c.962A>C p.N321T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.401); catalogued as COSV51831920; called by muse, mutect2, varscan2
- RASGEF1C | c.38del p.P13Qfs*34 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV63182978; called by mutect2, pindel
- RFTN1 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs373404854, COSV61918167; called by muse, mutect2, varscan2
- RSPH6A | c.1867G>C p.V623L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as COSV55570971; called by muse, mutect2, varscan2
- SEMA6C | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58999879; called by muse, mutect2, varscan2
- SIN3A | c.2876A>G p.Y959C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64583079; called by muse, mutect2, varscan2
- SLC5A6 | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV60158678; called by muse, mutect2, varscan2
- SPDYE5 | c.773T>C p.M258T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs587688003; called by muse, mutect2, varscan2
- TBC1D9 | c.2906G>C p.G969A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as COSV71307438; called by muse, mutect2, varscan2
- TMIE | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772275618, COSV58406122; called by mutect2, varscan2
- TRANK1 | c.3803C>T p.T1268M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs145261825; called by muse, mutect2, varscan2
- TTN | c.2331C>G p.I777M (on ENST00000591111; = p.I731M on NM_003319.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | PolyPhen benign (0.366); catalogued as rs1157627413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBG2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359157988; called by muse, mutect2, varscan2
- WDSUB1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754560559; called by muse, mutect2, varscan2
- ZBTB7B | c.515C>T p.S172F (on ENST00000292176; = p.S206F on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.675); catalogued as rs750545570; called by muse, mutect2
- ZFHX3 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150034422; called by mutect2, varscan2
- ZNF471 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs150662418; called by muse, mutect2, varscan2
- ZRSR2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57067574; called by muse, mutect2, varscan2
- ABLIM2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG7 | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADRA1A | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP9 | c.10994G>T p.G3665V (on ENST00000359028; = p.G3641V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ANGPTL2 | c.983A>C p.N328T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP002748.5 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.194); called by mutect2, varscan2
- ARFGEF1 | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARFGEF3 | c.662_665dup p.D223Kfs*2 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel
- ARHGEF19 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.102); called by muse, mutect2
- BAZ2B | c.3340G>A p.D1114N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); called by muse, mutect2
- BRIP1 | c.1802C>G p.S601* | Nonsense Mutation (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- C16orf96 | c.1916G>A p.G639D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAD | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- CAPN9 | c.542del p.N181Mfs*7 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel, varscan2
- CCDC150 | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC178 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC196 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CDH12 | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CDT1 | c.538_561del p.G180_P187del | In Frame Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CENPP | c.736+1G>T p.X246_splice | Splice Site (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- CEP350 | c.4560G>C p.Q1520H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CHKB | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CNTN2 | c.1035_1064del p.W346_R355del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- CRYGB | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CUZD1 | c.442A>T p.N148Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2D6 | c.1394G>A p.S465N | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- DDX50 | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2
- DGKK | c.3365G>C p.G1122A | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DOCK1 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- DST | c.3501_3505del p.Y1167* (on ENST00000361203 / NM_001374722.1; = p.Y841* on NM_001723.6) | Nonsense Mutation (DEL) | VAF 4/56 reads (7%) | called by mutect2, pindel*
- FLG | c.10639G>A p.G3547R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- FLG | c.3326G>T p.G1109V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FLG2 | c.5996G>A p.G1999E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FZD8 | c.1635_1653del p.V546Sfs*43 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- GABRP | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GFRA3 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GPR75 | c.102_109del p.Q34Hfs*44 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- HPCAL1 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- IGFN1 | c.2675T>C p.L892P (on ENST00000295591 / NM_001367841.1; = p.L3349P on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.334); called by muse, mutect2
- KDM5B | c.3587G>T p.R1196M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- KIAA0319 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- KIAA1522 | c.197C>T p.A66V (on ENST00000373480 / NM_001198972.2; = p.A125V on NM_020888.3) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.7226A>G p.D2409G (on ENST00000313654 / NM_198129.4; = p.D800G on NM_000227.6) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP4 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LRRC37A3 | c.4408G>A p.G1470S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEB4 | c.1001A>T p.Y334F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED28 | c.128C>G p.T43S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- METTL9 | c.915C>G p.Y305* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- MSH6 | c.2911G>C p.G971R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYCT1 | c.86del p.F29Sfs*28 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- MYO1G | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCBP3 | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NGEF | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR1A2 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2T1 | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- P3H2 | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PDE4A | c.1898A>C p.K633T (on ENST00000380702 / NM_001111307.2; = p.K394T on NM_006202.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by mutect2, varscan2
- PHLPP2 | c.3516C>A p.H1172Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIP4K2C | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- PLEKHA7 | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- POSTN | c.410_416del p.P137Lfs*19 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- PUM1 | c.546_549del p.H182Qfs*18 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- RBM12B | c.2691_2692insAAG p.D897_F898insK | In Frame Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel*, varscan2
- RP1 | c.4392A>T p.E1464D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RPRD2 | c.2892C>A p.D964E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RSPO1 | c.254del p.D85Afs*7 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- RUSC2 | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- RYR3 | c.4895C>G p.P1632R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELENON | c.1228_1232del p.S410Gfs*? | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by pindel, varscan2
- SF3B6 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SHE | c.825_839del p.R276_K280del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- SLC8A3 | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SLCO2A1 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SLCO6A1 | c.1481A>T p.K494M | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SNTG1 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TAF15 | c.1662T>A p.S554R (on ENST00000605844 / NM_139215.3; = p.S551R on NM_003487.4) | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TARS2 | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGM4 | c.1841C>G p.A614G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TOP1 | c.985_992del p.E329* | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- TRPM3 | c.401A>C p.Q134P (on ENST00000357533 / NM_001366142.2; = p.Q103P on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TTLL4 | c.3125C>G p.P1042R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TTN | c.27149T>C p.L9050P (on ENST00000591111; = p.L8123P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | PolyPhen possibly damaging (0.598); called by muse, varscan2
- ZCWPW2 | c.787_789del p.V263del | In Frame Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- ZNF117 | c.238del p.I80Yfs*8 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by pindel, varscan2
- AGPAT2 | c.657T>A p.T219= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- AOX1 | c.1116G>A p.L372= | Silent (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- CAPN8 | c.1806G>T p.T602= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV64814621; called by muse, mutect2, varscan2
- CDH20 | c.501C>T p.D167= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs150943040; called by mutect2, varscan2
- CNIH4 | c.174C>T p.V58= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- CRTAP | c.570C>T p.S190= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- DDX17 | c.183C>T p.A61= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs1402122914; called by muse, mutect2, varscan2
- DMC1 | c.699C>T p.F233= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99319264; called by mutect2, varscan2
- DTX2 | c.12C>T p.A4= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- HAP1 | c.423G>T p.G141= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- HECW2 | c.462C>T p.T154= | Silent (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- MAOB | c.18C>T p.D6= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- MNX1 | c.801G>A p.S267= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- NAA10 | c.141C>T p.D47= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs375877098, COSV64169761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFKBIA | c.486C>T p.V162= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- NLRP5 | c.2892G>A p.G964= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- OR2H2 | c.600C>G p.A200= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- OTP | c.924C>T p.I308= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- PHF20L1 | c.330T>A p.I110= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- PNN | c.258G>A p.L86= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- ROBO4 | c.1383G>A p.L461= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- SEPTIN3 | c.324C>T p.I108= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs118016225; called by muse, mutect2, varscan2
- SHPRH | c.1488G>A p.V496= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1209205772; called by muse, mutect2, varscan2
- SHROOM4 | c.1923T>G p.S641= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TAB1 | c.1284C>T p.D428= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs569304396, COSV53371606; called by muse, mutect2, varscan2
- TMEM183A | c.279C>T p.I93= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1179340324; called by muse, mutect2, varscan2
- TTN | c.27060C>T p.D9020= (on ENST00000591111; = p.D8093= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs757848062, COSV59877821; called by muse, varscan2
- USP43 | c.417C>A p.G139= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- ZNF516 | c.2640C>T p.P880= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs368789387; called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621958 del GCTCCTGCAGCGGGCACCGCT | 5'Flank (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- APOLD1 | c.97-22188T>C | Intron (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- ARL11 | c.*259T>C | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, varscan2
- CT83 | c.-11G>A | 5'UTR (SNP) | VAF 8/94 reads (9%) | catalogued as rs200634429, COSV100902502, COSV100902514; called by muse, mutect2
- FYB1 | c.*23T>A | 3'UTR (SNP) | VAF 28/227 reads (12%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34504A>G | Intron (SNP) | VAF 11/141 reads (8%) | called by muse, mutect2
- KBTBD11 | c.*2242T>G | 3'UTR (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- KCNA4 | c.-563T>G | 5'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV60256085; called by mutect2, varscan2
- LIAS | c.299+1592G>C | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- LINC01565 | n.851G>C | RNA (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2, varscan2
- LRATD1 | c.*3087G>A | 3'UTR (SNP) | VAF 11/65 reads (17%) | catalogued as rs1232280132; called by muse, mutect2, varscan2
- MICAL3 | c.2242-739A>G | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as rs746133648; called by muse, mutect2, varscan2
- NPY2R | c.*1057A>G | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- OR7D2 | c.*1651T>C | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- PDP2 | c.*1835G>T | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, varscan2
- PLCE1 | c.*72del | 3'UTR (DEL) | VAF 62/168 reads (37%) | called by mutect2, varscan2
- PSMA6 | c.*21G>A | 3'UTR (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99809287; called by mutect2, varscan2
- TAFA4 | c.*8A>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as rs1156458456; called by muse, mutect2, varscan2
- TCP10L3 | n.2664G>C | RNA (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
